Somatic mutation profile of cancer-model specimen HCM-CSHL-0245-C18-85M (3D Organoid; aliquot HCM-CSHL-0245-C18-85M-01D-A79M-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0245-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: GB; Age at diagnosis: 72.9 years (26,617 days).
Specimen HCM-CSHL-0245-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41e52bdd-d0e0-4567-ad4c-17d60e12393c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0245-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0245-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc739216-5669-4852-ac56-52ad4312848b

The open-access MAF lists 215 somatic variants for this specimen: 151 protein-altering or splice-affecting, 52 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 52, Nonsense Mutation 12, Intron 7, Frame Shift Del 4, RNA 2, Frame Shift Ins 2, 5'Flank 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.621G>T p.W207C | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99031505; called by muse, mutect2, varscan2
- AARD | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 109/786 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs534177737; called by muse, mutect2, varscan2
- ADCY2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 140/319 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as rs1168542317, COSV57861690, COSV57864042; called by muse, mutect2, varscan2
- ADGRB2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 222/474 reads (47%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as rs1398217020; called by muse, varscan2
- ADIPOR1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 122/261 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.019); catalogued as rs1040065193, COSV61852058; called by muse, mutect2, varscan2
- ANKRD30B | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV100745841; called by muse, mutect2, varscan2
- ARMCX2 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 263/557 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1259351624, COSV57529232; called by muse, mutect2, varscan2
- ATM | c.3208G>A p.V1070I | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs587780620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10D | c.3670G>T p.D1224Y | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV56711130; called by muse, mutect2, varscan2
- ATP9B | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 128/274 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs774905035; called by muse, mutect2, varscan2
- BMP8A | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs1460803803; called by muse, mutect2, varscan2
- CCDC158 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 192/374 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as rs1329795418, COSV101187423, COSV66355999; called by muse, mutect2, varscan2
- CCDC69 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 330/330 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs747546885; called by muse, mutect2, varscan2
- CHRNB4 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 203/409 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55718615; called by muse, mutect2, varscan2
- CLASP1 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 159/316 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs763851949, COSV55320925; called by muse, mutect2, varscan2
- CRB1 | c.4090G>T p.V1364F | Missense Mutation (SNP) | VAF 163/329 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1437858539; called by muse, mutect2, varscan2
- CST5 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 118/268 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs771464838, COSV59013838; called by muse, mutect2
- DCDC1 | c.2060G>A p.R687K | Missense Mutation (SNP) | VAF 75/333 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as COSV100663131; called by muse, mutect2, varscan2
- ENO3 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs534374372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLAD1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 198/393 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs201824694; called by muse, mutect2, varscan2
- FLRT3 | c.302A>T p.N101I | Missense Mutation (SNP) | VAF 104/242 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs374161251; called by muse, mutect2, varscan2
- FMO3 | c.1547A>C p.K516T | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as COSV63006591; called by muse, mutect2, varscan2
- GPC2 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 268/831 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs1193193792; called by muse, mutect2, varscan2
- HHLA1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 362/362 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764177411; called by muse, mutect2, varscan2
- HIVEP3 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 196/422 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs150086203; called by muse, mutect2, varscan2
- IGFN1 | c.2752C>T p.R918W (on ENST00000295591 / NM_001367841.1; = p.R3375W on NM_001164586.2) | Missense Mutation (SNP) | VAF 106/393 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276928055; called by muse, varscan2
- IL7R | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 183/311 reads (59%) | catalogued as CM056607, COSV57409143; called by muse, mutect2
- KCNV1 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 46/365 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV52089738; called by muse, mutect2, varscan2
- KRTAP19-1 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 196/434 reads (45%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.155); catalogued as COSV101185867; called by muse, mutect2, varscan2
- LIN28A | c.154G>C p.G52R | Missense Mutation (SNP) | VAF 289/564 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99575437; called by muse, mutect2, varscan2
- LRCH1 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 55/378 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as rs1329151592; called by muse, mutect2, varscan2
- LRP2 | c.4345G>A p.D1449N | Missense Mutation (SNP) | VAF 143/322 reads (44%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.794); catalogued as rs772588594, COSV55547681; called by muse, mutect2, varscan2
- MAST1 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 102/368 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52241239; called by muse, mutect2, varscan2
- NFATC1 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 151/308 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781365067, COSV53702141; called by muse, mutect2, varscan2
- NME8 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs368696812, COSV52248056; called by muse, mutect2, varscan2
- OR4A16 | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 60/60 reads (100%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); catalogued as COSV59042872, COSV59045268; called by muse, mutect2, varscan2
- PASD1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 85/368 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs762258468, COSV64856169; called by muse, varscan2
- PIWIL1 | c.2051G>T p.R684M | Missense Mutation (SNP) | VAF 79/372 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV55350465; called by muse, mutect2, varscan2
- PKHD1L1 | c.8669T>C p.I2890T | Missense Mutation (SNP) | VAF 326/326 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1425471818; called by muse, mutect2, varscan2
- PPP1R3A | c.1885G>T p.D629Y | Missense Mutation (SNP) | VAF 134/264 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs533288037; called by muse, mutect2, varscan2
- RAPGEF2 | c.943A>T p.K315* | Nonsense Mutation (SNP) | VAF 125/242 reads (52%) | catalogued as COSV52427435; called by muse, mutect2, varscan2
- RASGRF2 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs747963579, COSV54131808; called by muse, mutect2, varscan2
- RHBDL3 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 170/516 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761559210, COSV52189142; called by muse, mutect2, varscan2
- SDK1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 113/349 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs376569849; called by muse, mutect2, varscan2
- SLC14A2 | c.2453C>T p.A818V | Missense Mutation (SNP) | VAF 181/400 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs748642786, COSV104369992; called by muse, mutect2, varscan2
- SMOC1 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 153/342 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs752262272, COSV62761244; called by muse, mutect2, varscan2
- SORCS1 | c.2416G>C p.D806H | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.275); catalogued as COSV99551305; called by muse, mutect2, varscan2
- SSTR3 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 269/557 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs766144463; called by muse, mutect2, varscan2
- TICAM1 | c.1424G>C p.S475T | Missense Mutation (SNP) | VAF 180/397 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV99940989; called by muse, mutect2, varscan2
- TLN2 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 164/327 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); catalogued as COSV60891559; called by muse, mutect2, varscan2
- TMEM63C | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 198/433 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs866211915, COSV53601252; called by muse, mutect2, varscan2
- TRAF2 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 37/452 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs532828294, COSV56036404; called by muse, mutect2
- UNC5D | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 96/556 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.31); catalogued as rs1051399058; called by muse, mutect2, varscan2
- UPF3B | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 114/513 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as rs1218778977; called by muse, varscan2
- UTP18 | c.873C>G p.I291M | Missense Mutation (SNP) | VAF 126/405 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99834880; called by muse, mutect2, varscan2
- VNN1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763783408, COSV63389358; called by muse, mutect2, varscan2
- ZBBX | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 191/327 reads (58%) | catalogued as rs770966283; called by muse, mutect2, varscan2
- ZFP28 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 122/246 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373914867, COSV56736279; called by muse, mutect2, varscan2
- ZNF536 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 197/427 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.415); catalogued as rs774965623, COSV62833030; called by muse, mutect2, varscan2
- ZNF717 | c.2177G>T p.R726L | Missense Mutation (SNP) | VAF 166/516 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV68858615; called by muse, varscan2
- ABCA13 | c.12803C>T p.T4268I | Missense Mutation (SNP) | VAF 108/389 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ABCA9 | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 102/324 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- AC069544.2 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 211/415 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ACSS3 | c.1446C>A p.Y482* | Nonsense Mutation (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- ADGRG4 | c.1517C>G p.S506* | Nonsense Mutation (SNP) | VAF 218/439 reads (50%) | called by muse, mutect2, varscan2
- AHNAK2 | c.5779G>A p.D1927N | Missense Mutation (SNP) | VAF 188/190 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- AKT3 | c.875T>A p.L292H | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALOX15B | c.1183T>A p.C395S | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- AP3S2 | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- APOBEC3C | c.65A>T p.K22I | Missense Mutation (SNP) | VAF 143/295 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ARHGAP24 | c.1052A>T p.K351M (on ENST00000395184 / NM_001025616.3; = p.K258M on NM_031305.3) | Missense Mutation (SNP) | VAF 82/408 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ASCC2 | c.1379dup p.A462Cfs*23 | Frame Shift Ins (INS) | VAF 130/358 reads (36%) | called by mutect2, pindel, varscan2
- CCDC18 | c.3835G>A p.D1279N (on ENST00000343253 / NM_001306076.1; = p.D1280N on NM_206886.4) | Missense Mutation (SNP) | VAF 99/204 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CLCC1 | c.780G>C p.W260C (on ENST00000356970 / NM_001377464.1; = p.W210C on NM_015127.5) | Missense Mutation (SNP) | VAF 131/245 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC14A | c.74C>A p.T25N | Missense Mutation (SNP) | VAF 516/888 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- CMPK2 | c.1223A>C p.Q408P | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CNTN2 | c.1024T>C p.S342P | Missense Mutation (SNP) | VAF 96/402 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- COX5A | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 134/283 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- CPN1 | c.1100A>T p.D367V | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSPG4 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 233/500 reads (47%) | called by muse, mutect2, varscan2
- CTNNA1 | c.2529C>A p.Y843* | Nonsense Mutation (SNP) | VAF 340/341 reads (100%) | called by muse, mutect2, varscan2
- DHX38 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2
- DOP1A | c.977A>T p.E326V | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- DSP | c.7617dup p.D2540* | Frame Shift Ins (INS) | VAF 357/686 reads (52%) | called by mutect2, pindel, varscan2
- EBF1 | c.1693C>A p.Q565K | Missense Mutation (SNP) | VAF 161/417 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- EXOC3L1 | c.2185C>A p.P729T | Missense Mutation (SNP) | VAF 302/637 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FBH1 | c.1558G>T p.G520W (on ENST00000362091 / NM_178150.3; = p.G571W on NM_032807.4) | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FER1L5 | c.3226C>T p.Q1076* (on ENST00000623019; = p.Q1049* on NM_001293083.2) | Nonsense Mutation (SNP) | VAF 110/574 reads (19%) | called by muse, mutect2, varscan2
- FMN2 | c.3770del p.P1257Hfs*18 | Frame Shift Del (DEL) | VAF 109/429 reads (25%) | called by mutect2, pindel, varscan2
- FOXN2 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 160/334 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GALNT13 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 127/246 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- GAREM2 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 107/423 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- GDPGP1 | c.955del p.S319Afs*4 | Frame Shift Del (DEL) | VAF 189/465 reads (41%) | called by mutect2, pindel, varscan2
- GINS2 | c.440A>G p.N147S | Missense Mutation (SNP) | VAF 136/264 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2
- HAND2 | c.313A>T p.N105Y | Missense Mutation (SNP) | VAF 63/639 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- HYDIN | c.10384C>T p.R3462* | Nonsense Mutation (SNP) | VAF 119/246 reads (48%) | called by muse, mutect2, varscan2
- ITPR3 | c.7054G>A p.E2352K | Missense Mutation (SNP) | VAF 293/427 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JAK2 | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- KLHL34 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 305/594 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KMT2D | c.729C>G p.F243L | Missense Mutation (SNP) | VAF 199/411 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- KRT24 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 137/450 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- KRTAP1-3 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 140/911 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAFB | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 120/550 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEB18 | c.300G>C p.E100D | Missense Mutation (SNP) | VAF 234/449 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAP2 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 155/344 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MAP4 | c.1981C>T p.L661F | Missense Mutation (SNP) | VAF 125/444 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- MEI4 | c.385C>G p.H129D | Missense Mutation (SNP) | VAF 336/498 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MROH2A | c.808C>A p.H270N | Missense Mutation (SNP) | VAF 118/268 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRPL55 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 95/352 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MUC12 | c.3514C>G p.P1172A (on ENST00000379442; = p.P1029A on NM_001164462.1) | Missense Mutation (SNP) | VAF 32/1020 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.55); called by muse, mutect2
- MUC16 | c.25969C>A p.H8657N | Missense Mutation (SNP) | VAF 189/432 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MXRA5 | c.7283G>A p.R2428K | Missense Mutation (SNP) | VAF 271/609 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.682); called by muse, mutect2
- NISCH | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 238/547 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- NLRP2 | c.2313T>A p.F771L | Missense Mutation (SNP) | VAF 254/480 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOLC1 | c.385A>C p.S129R | Missense Mutation (SNP) | VAF 109/245 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NR2F1 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 228/583 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAK3 | c.1671C>A p.S557R (on ENST00000262836 / NM_001324328.2; = p.S542R on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/297 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by mutect2, varscan2
- PCDHGB5 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 103/379 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PCSK5 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 25/419 reads (6%) | called by muse, mutect2
- PDCD6IP | c.1629G>A p.M543I | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.1531A>C p.S511R | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDPN | c.430T>G p.F144V (on ENST00000621990; = p.F220V on NM_006474.4) | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PICALM | c.321C>A p.S107R | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.182); called by mutect2, varscan2
- PLEC | c.1048C>T p.Q350* (on ENST00000322810 / NM_201380.4; = p.Q240* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 128/380 reads (34%) | called by muse, mutect2, varscan2
- PMPCB | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 60/403 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PRUNE2 | c.1513C>A p.Q505K | Missense Mutation (SNP) | VAF 80/444 reads (18%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- PTPRT | c.4251A>T p.K1417N | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRU | c.1120C>A p.L374I | Missense Mutation (SNP) | VAF 203/406 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RB1CC1 | c.925T>G p.L309V | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RBM42 | c.1191G>T p.L397F | Missense Mutation (SNP) | VAF 24/409 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- SHANK1 | c.6185C>A p.S2062Y | Missense Mutation (SNP) | VAF 278/564 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- SLC1A4 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 205/383 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- SMS | c.517A>G p.S173G | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SORCS1 | c.2417A>T p.D806V | Missense Mutation (SNP) | VAF 59/303 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- STOX1 | c.172_222delinsA p.R59Afs*30 | Frame Shift Del (DEL) | VAF 72/295 reads (24%) | called by pindel, varscan2*
- TBC1D8B | c.3068T>C p.L1023S | Missense Mutation (SNP) | VAF 28/413 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TBCD | c.1338G>T p.K446N | Missense Mutation (SNP) | VAF 172/460 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- TDRKH | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2
- TOPAZ1 | c.1109A>C p.K370T | Missense Mutation (SNP) | VAF 250/353 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TRAFD1 | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 85/343 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TUT7 | c.2837T>G p.F946C | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- WNK2 | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 234/386 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WWOX | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDHHC23 | c.1088C>G p.A363G | Missense Mutation (SNP) | VAF 154/488 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFP36L1 | c.436del p.S146Afs*2 | Frame Shift Del (DEL) | VAF 219/561 reads (39%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.550_588del p.R184_L196del | In Frame Del (DEL) | VAF 123/623 reads (20%) | called by mutect2, varscan2
- ZNF600 | c.976G>T p.G326* | Nonsense Mutation (SNP) | VAF 92/224 reads (41%) | called by mutect2, varscan2
- ZNF737 | c.1583A>C p.K528T | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ZNF74 | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ZNRF3 | c.689C>T p.S230F (on ENST00000544604 / NM_001206998.2; = p.S130F on NM_032173.3) | Missense Mutation (SNP) | VAF 150/359 reads (42%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ZRANB3 | c.1906T>A p.S636T | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ABCA13 | c.12441A>T p.S4147= | Silent (SNP) | VAF 89/270 reads (33%) | catalogued as COSV101446923; called by muse, mutect2, varscan2
- ADORA1 | c.616C>T p.L206= | Silent (SNP) | VAF 249/481 reads (52%) | called by muse, mutect2, varscan2
- ALAS1 | c.717C>T p.L239= | Silent (SNP) | VAF 185/644 reads (29%) | catalogued as COSV59628619; called by muse, mutect2, varscan2
- ANKRD28 | c.390G>A p.L130= | Silent (SNP) | VAF 82/535 reads (15%) | called by muse, mutect2, varscan2
- ASB14 | c.954T>C p.V318= | Silent (SNP) | VAF 172/523 reads (33%) | called by muse, mutect2, varscan2
- BCOR | c.2721C>T p.S907= | Silent (SNP) | VAF 214/518 reads (41%) | catalogued as rs1349371387; called by muse, mutect2, varscan2
- CARD11 | c.627A>G p.A209= | Silent (SNP) | VAF 348/529 reads (66%) | called by muse, mutect2, varscan2
- CD200R1 | c.126C>T p.L42= (on ENST00000471858 / NM_170780.3; = p.L65= on NM_138806.4) | Silent (SNP) | VAF 105/383 reads (27%) | catalogued as rs897611284; called by muse, mutect2, varscan2
- CHRNA4 | c.345C>T p.S115= | Silent (SNP) | VAF 245/399 reads (61%) | catalogued as rs201033859, COSV100937285; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHST10 | c.622C>A p.R208= | Silent (SNP) | VAF 170/334 reads (51%) | called by muse, mutect2, varscan2
- COL12A1 | c.2664G>T p.A888= | Silent (SNP) | VAF 36/601 reads (6%) | catalogued as rs756052823; called by muse, mutect2
- CUBN | c.10212C>A p.G3404= | Silent (SNP) | VAF 140/299 reads (47%) | called by muse, mutect2, varscan2
- DHX16 | c.2124G>T p.S708= | Silent (SNP) | VAF 161/539 reads (30%) | catalogued as rs906936810; called by muse, mutect2, varscan2
- DHX58 | c.558G>A p.L186= | Silent (SNP) | VAF 321/500 reads (64%) | called by muse, mutect2, varscan2
- EPB41L2 | c.2790T>C p.S930= | Silent (SNP) | VAF 185/543 reads (34%) | called by muse, mutect2, varscan2
- G6PC3 | c.879G>A p.L293= | Silent (SNP) | VAF 382/638 reads (60%) | catalogued as rs780718603; ClinVar: likely benign; called by muse, mutect2, varscan2
- GJA3 | c.627G>A p.A209= | Silent (SNP) | VAF 228/803 reads (28%) | catalogued as rs1278306213; called by muse, mutect2, varscan2
- GLIS2 | c.1245G>A p.P415= | Silent (SNP) | VAF 388/796 reads (49%) | catalogued as rs755435780; ClinVar: likely benign; called by muse, mutect2
- GOLGA8A | c.1599C>T p.H533= (on ENST00000432566; = p.H505= on NM_181077.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 89/374 reads (24%) | catalogued as rs1480564491; called by muse, mutect2, varscan2
- IGF2 | c.462G>A p.P154= (on ENST00000434045 / NM_001127598.3; = p.P98= on NM_000612.6) | Silent (SNP) | VAF 345/346 reads (100%) | catalogued as COSV56097151; called by muse, mutect2, varscan2
- KCTD8 | c.759C>T p.N253= | Silent (SNP) | VAF 249/505 reads (49%) | catalogued as COSV63592481; called by muse, mutect2, varscan2
- KIF13A | c.4794C>A p.G1598= | Silent (SNP) | VAF 42/590 reads (7%) | called by muse, mutect2
- LDOC1 | c.408C>T p.D136= | Silent (SNP) | VAF 187/395 reads (47%) | catalogued as COSV100983116; called by muse, mutect2, varscan2
- LOXHD1 | c.1641C>T p.R547= | Silent (SNP) | VAF 133/271 reads (49%) | called by muse, mutect2, varscan2
- MDN1 | c.3642G>C p.R1214= | Silent (SNP) | VAF 208/350 reads (59%) | called by muse, mutect2, varscan2
- MDN1 | c.1416C>T p.H472= | Silent (SNP) | VAF 439/553 reads (79%) | called by muse, mutect2, varscan2
- MTO1 | c.123C>G p.V41= | Silent (SNP) | VAF 268/821 reads (33%) | catalogued as rs1351045114; called by muse, mutect2, varscan2
- MYO1E | c.1335C>T p.I445= | Silent (SNP) | VAF 119/251 reads (47%) | catalogued as rs200815044, COSV55690417; called by muse, mutect2, varscan2
- NHS | c.321C>T p.G107= | Silent (SNP) | VAF 133/577 reads (23%) | called by muse, varscan2
- OS9 | c.1911C>T p.R637= | Silent (SNP) | VAF 131/254 reads (52%) | catalogued as rs754652717; called by muse, mutect2, varscan2
- PCDH9 | c.1239G>A p.A413= | Silent (SNP) | VAF 142/452 reads (31%) | catalogued as rs372255783; called by muse, varscan2
- PHF2 | c.2790C>T p.I930= | Silent (SNP) | VAF 271/394 reads (69%) | catalogued as rs148663364; called by muse, mutect2, varscan2
- POM121L12 | c.585G>A p.P195= | Silent (SNP) | VAF 291/832 reads (35%) | catalogued as rs781667306, COSV68692555; called by muse, mutect2, varscan2
- RASGRF1 | c.1650C>T p.I550= | Silent (SNP) | VAF 149/304 reads (49%) | catalogued as rs756158411, COSV69176724; called by muse, mutect2, varscan2
- RHOBTB1 | c.624G>A p.L208= | Silent (SNP) | VAF 175/371 reads (47%) | catalogued as rs772792443; called by muse, mutect2, varscan2
- RNF224 | c.258G>A p.L86= | Silent (SNP) | VAF 226/724 reads (31%) | called by muse, mutect2, varscan2
- RP1 | c.1176A>T p.T392= | Silent (SNP) | VAF 43/254 reads (17%) | called by muse, mutect2, varscan2
- RTP1 | c.642C>T p.T214= | Silent (SNP) | VAF 54/949 reads (6%) | called by muse, mutect2
- SCN1B | c.570G>A p.E190= | Silent (SNP) | VAF 103/244 reads (42%) | called by muse, mutect2, varscan2
- SCN5A | c.987C>T p.S329= | Silent (SNP) | VAF 101/365 reads (28%) | called by muse, mutect2, varscan2
- SI | c.3297C>T p.F1099= | Silent (SNP) | VAF 141/457 reads (31%) | called by muse, mutect2, varscan2
- SLC35F1 | c.888C>A p.L296= | Silent (SNP) | VAF 112/393 reads (28%) | called by muse, mutect2, varscan2
- SUSD4 | c.381C>T p.I127= | Silent (SNP) | VAF 107/268 reads (40%) | catalogued as rs776519802, COSV59553299; called by muse, mutect2, varscan2
- TPO | c.1287C>T p.S429= | Silent (SNP) | VAF 265/505 reads (52%) | called by muse, mutect2, varscan2
- TRAV26-1 | c.282C>T p.H94= | Silent (SNP) | VAF 144/288 reads (50%) | catalogued as rs757745985; called by muse, mutect2, varscan2
- TXNDC11 | c.99C>T p.L33= | Silent (SNP) | VAF 368/807 reads (46%) | catalogued as COSV51601050; called by muse, mutect2
- UBQLNL | c.1122T>A p.T374= | Silent (SNP) | VAF 82/330 reads (25%) | called by muse, mutect2, varscan2
- USP35 | c.1665C>T p.P555= | Silent (SNP) | VAF 368/368 reads (100%) | catalogued as rs376772946; called by muse, mutect2, varscan2
- WDFY4 | c.2889T>C p.A963= | Silent (SNP) | VAF 63/316 reads (20%) | called by muse, mutect2, varscan2
- ZIC1 | c.285C>T p.N95= | Silent (SNP) | VAF 294/936 reads (31%) | called by muse, mutect2, varscan2
- ZNF358 | c.435C>A p.A145= | Silent (SNP) | VAF 32/511 reads (6%) | called by muse, mutect2
- ZNF618 | c.2013G>T p.L671= (on ENST00000374126 / NM_001318042.2; = p.L578= on NM_133374.2) | Silent (SNP) | VAF 20/644 reads (3%) | called by muse, mutect2
- C2CD6 | c.1581+2045G>C | Intron (SNP) | VAF 69/300 reads (23%) | catalogued as COSV53796659; called by muse, mutect2, varscan2
- CBARP | c.1214+118C>A | Intron (SNP) | VAF 298/637 reads (47%) | called by muse, mutect2, varscan2
- DIRC1 | n.495T>A | RNA (SNP) | VAF 66/303 reads (22%) | called by muse, mutect2, varscan2
- DNAH14 | c.5585-5934dup | Intron (INS) | VAF 28/132 reads (21%) | catalogued as rs759082488; called by mutect2, varscan2
- G6PD | c.-4C>T | 5'UTR (SNP) | VAF 285/432 reads (66%) | catalogued as rs781792803; called by muse, mutect2, varscan2
- LINC01018 | n.1185C>A | RNA (SNP) | VAF 209/519 reads (40%) | called by muse, mutect2, varscan2
- NRG1 | chr8:31640163 C>A | 5'Flank (SNP) | VAF 412/490 reads (84%) | called by mutect2, varscan2
- ROBO2 | c.3761-2230C>A | Intron (SNP) | VAF 83/285 reads (29%) | called by muse, mutect2, varscan2
- RXFP1 | c.465-908A>G | Intron (SNP) | VAF 154/336 reads (46%) | catalogued as rs1015594014, COSV57048211; called by muse, mutect2, varscan2
- STOX1 | c.310+198_310+248delinsA | Intron (DEL) | VAF 55/316 reads (17%) | called by pindel, varscan2*
- TTN | c.34265-3224C>A | Intron (SNP) | VAF 11/18 reads (61%) | catalogued as rs1449282705; called by mutect2, varscan2
- UNC45A | chr15:90934125 C>A | 5'Flank (SNP) | VAF 27/392 reads (7%) | called by muse, mutect2
